CGCI case BLGSP-71-30-00781 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a780e596-6b32-48eb-80da-aa472c2997a1

Demographics
Sex at birth: male; Age at index: 30 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 30.5 years (11,137 days); Year of diagnosis: 2010; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,845 days (5.1 years); Ann Arbor extranodal involvement: No; Max tumor bulk site: Axillary lymph nodes.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 11 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 11 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 11 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 11 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 1,845 days (5.1 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day -1,431, day 404.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (Flow Cytometry): Positive; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- FMC-7 (Flow Cytometry): Positive; Specialized molecular test: FMC-7.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (Cytogenetics, NOS): Abnormal, NOS.
- Lactate Dehydrogenase 197 [Blood test normal range upper: 210].

Other clinical attributes
- Day -1,431: Risk factors: HIV/AIDS.
- Day -1,431: Comorbidities: HIV/AIDS.
- Day 0: Risk factors: Epstein-Barr Virus.
- Day 0: Comorbidities: Cytomegalovirus (CMV).
- Day 0: Comorbidities: Epstein-Barr Virus.
- Day 0: Weight: 69.14 kg; Height: 183 cm; BMI: 20.6; CD4 count: 380; Haart treatment indicator: Yes; HIV viral load: 40.
- Day 0: Risk factors: Cytomegalovirus (CMV).
- Day 1,845: Nadir CD4 count: 230.

Biospecimens (2 samples)
- Sample BLGSP-71-30-00781-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00781-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; History immunosuppresive diagnosis other: CMV, Epstein-Barr Virus.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 197; Immunophenotypic analysis method: Flow cytometry, not otherwise specified.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: FMC7.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc; Genetic abnormality method other: Cytogenetics.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOXMR/IVACR (Magrath Protocol); Pharma adjuvant cycles count: 4.
